Somatic mutation profile of tumor specimen MMRF_2655_1_BM_CD138pos (aliquot MMRF_2655_1_BM_CD138pos_T1_KHS5U_L14266) from MMRF case MMRF_2655, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.7 years (23,635 days).
Specimen MMRF_2655_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d41fe06b-8733-44c9-a286-7624a6aeee8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2655_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2655_1_PB_WBC_C3_KHS5U_L14267; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6af2ccb-7acc-42f3-81d9-ee2329662eb7

The open-access MAF lists 127 somatic variants for this specimen: 46 protein-altering or splice-affecting, 16 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 34, Intron 18, Silent 16, 5'UTR 8, RNA 5, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ELMO2 | c.1802-1G>C p.X601_splice | Splice Site (SNP) | VAF 12/338 reads (4%) | catalogued as rs886037918; ClinVar: pathogenic; called by muse, mutect2
- COQ10A | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs148374703, COSV57524829; called by muse, mutect2, varscan2
- CYTIP | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs756398323, COSV99938588, COSV99938736; called by muse, mutect2, varscan2
- ESCO1 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 40/447 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs913791683; called by muse, mutect2
- FBN3 | c.6230G>A p.G2077D | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1419127690; called by muse, mutect2, varscan2
- IGHV2-70 | c.305C>A p.T102K | Missense Mutation (SNP) | VAF 86/108 reads (80%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs369201986; called by muse, varscan2
- LAMC2 | c.2427C>A p.D809E | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.137); catalogued as rs368858792, COSV51459703; called by muse, mutect2, varscan2
- MINDY2 | c.1024A>G p.R342G | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV57506845; called by muse, mutect2, varscan2
- NRAP | c.4373C>G p.T1458R (on ENST00000359988 / NM_001322945.2; = p.T1423R on NM_006175.4) | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.13); catalogued as COSV100748665; called by muse, mutect2, varscan2
- NRG1 | c.167G>A p.S56N (on ENST00000523534; = p.S203N on NM_013962.2) | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as rs544233379; called by muse, mutect2, varscan2
- SVEP1 | c.6730G>T p.V2244F | Missense Mutation (SNP) | VAF 85/289 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs1277211903, COSV52838509; called by muse, mutect2, varscan2
- TAOK3 | c.1330G>A p.V444I | Missense Mutation (SNP) | VAF 22/619 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.206); catalogued as COSV66827551; called by muse, mutect2
- TNKS | c.3736C>T p.H1246Y | Missense Mutation (SNP) | VAF 102/265 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV60057419; called by muse, mutect2, varscan2
- TRIM37 | c.2020A>T p.M674L | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as rs1568017752; called by muse, mutect2, varscan2
- TSEN2 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as rs763202098, COSV53190754; called by muse, mutect2, varscan2
- WDFY3 | c.6614C>A p.T2205N | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV55697723; called by muse, mutect2
- ZNF527 | c.881G>T p.R294I | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1312212461, COSV62230130; called by muse, mutect2, varscan2
- AC004593.2 | c.465C>A p.Y155* | Nonsense Mutation (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- ADRA2C | c.1339T>A p.S447T | Missense Mutation (SNP) | VAF 165/385 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- ASIC5 | c.1029C>A p.D343E | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- BAHCC1 | c.76_89del p.A26Rfs*69 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | called by mutect2, pindel, varscan2
- BSN | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2
- CBFB | c.456dup p.F153Ifs*2 | Frame Shift Ins (INS) | VAF 62/120 reads (52%) | called by mutect2, pindel, varscan2
- CDK8 | c.403A>T p.I135F | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- CPS1 | c.4036T>C p.F1346L | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2
- CRELD1 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 10/244 reads (4%) | called by muse, mutect2
- CUL7 | c.2377A>G p.I793V | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.02); called by muse, mutect2
- INPP5J | c.2078C>T p.P693L (on ENST00000331075 / NM_001284285.2; = p.P325L on NM_001002837.2) | Missense Mutation (SNP) | VAF 88/118 reads (75%) | SIFT tolerated (0.07); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- IRF2BPL | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- JMJD1C | c.2275A>T p.T759S | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MN1 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 68/80 reads (85%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRPS10 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MYO16 | c.5379T>G p.N1793K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- NALCN | c.296A>T p.D99V | Missense Mutation (SNP) | VAF 61/69 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- OPTC | c.416A>G p.Y139C | Missense Mutation (SNP) | VAF 25/420 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR12D3 | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2
- PHLPP1 | c.384G>C p.R128S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- PREP | c.1510C>T p.L504F (on ENST00000369110; = p.L570F on NM_002726.5) | Missense Mutation (SNP) | VAF 126/259 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PRSS23 | c.530T>C p.I177T | Missense Mutation (SNP) | VAF 44/320 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SLC34A1 | c.466dup p.V156Gfs*57 | Frame Shift Ins (INS) | VAF 97/229 reads (42%) | called by mutect2, pindel, varscan2
- TRAF3 | c.1425del p.F475Lfs*20 | Frame Shift Del (DEL) | VAF 75/132 reads (57%) | called by mutect2, pindel, varscan2
- WDFY3 | c.8620C>G p.L2874V | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- WDR3 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- YTHDF3 | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 53/484 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ZBED4 | c.2798T>A p.V933E | Missense Mutation (SNP) | VAF 152/226 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ZNF792 | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 82/269 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCF3 | c.1096C>T p.L366= | Silent (SNP) | VAF 48/141 reads (34%) | called by muse, mutect2, varscan2
- ADGRG3 | c.1398C>T p.V466= | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as rs780755886; called by muse, mutect2, varscan2
- C8orf58 | c.927C>A p.I309= (on ENST00000289989 / NM_001013842.3; = p.I301= on NM_173686.3) | Silent (SNP) | VAF 107/258 reads (41%) | called by muse, mutect2, varscan2
- FAT4 | c.11308C>A p.R3770= | Silent (SNP) | VAF 63/204 reads (31%) | catalogued as rs761118468, COSV100628354; called by muse, mutect2, varscan2
- H1-2 | c.159G>A p.E53= | Silent (SNP) | VAF 114/215 reads (53%) | catalogued as rs529286462, COSV59191775, COSV59193287; called by muse, mutect2, varscan2
- INTU | c.1245T>C p.Y415= | Silent (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- IRX1 | c.120G>T p.S40= | Silent (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
- MIB2 | c.1956G>C p.V652= | Silent (SNP) | VAF 26/134 reads (19%) | called by muse, mutect2, varscan2
- OR4F15 | c.84T>C p.F28= | Silent (SNP) | VAF 210/666 reads (32%) | called by muse, mutect2, varscan2
- OR5W2 | c.843G>T p.V281= | Silent (SNP) | VAF 32/318 reads (10%) | catalogued as COSV100747569; called by muse, mutect2
- P4HA3 | c.231G>A p.E77= | Silent (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- PCNX3 | c.51C>A p.L17= | Silent (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- PROP1 | c.288C>A p.I96= | Silent (SNP) | VAF 44/346 reads (13%) | called by muse, mutect2, varscan2
- SEC13 | c.291C>T p.H97= (on ENST00000350697 / NM_183352.3; = p.H100= on NM_030673.4) | Silent (SNP) | VAF 26/182 reads (14%) | catalogued as rs376073337; called by muse, mutect2, varscan2
- TMOD3 | c.723C>T p.D241= | Silent (SNP) | VAF 11/324 reads (3%) | called by muse, mutect2
- ZNF479 | c.465A>G p.K155= | Silent (SNP) | VAF 112/260 reads (43%) | called by muse, mutect2, varscan2
- AC024651.2 | n.83T>A | RNA (SNP) | VAF 21/234 reads (9%) | called by muse, mutect2
- ADAM7 | c.*47A>G | 3'UTR (SNP) | VAF 69/220 reads (31%) | called by muse, mutect2, varscan2
- ADGRE1 | c.-11A>G | 5'UTR (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- ADH1B | c.259+22A>G | Intron (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- AHCTF1 | c.*1269del | 3'UTR (DEL) | VAF 113/917 reads (12%) | called by mutect2, pindel, varscan2
- AKR1B15 | c.435+38G>A | Intron (SNP) | VAF 99/215 reads (46%) | catalogued as rs1168705170; called by muse, mutect2, varscan2
- ANGPT1 | c.*2072A>C | 3'UTR (SNP) | VAF 11/31 reads (35%) | catalogued as rs1264463611; called by muse, mutect2, varscan2
- ANKRD18B | c.2992-925A>G | Intron (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- ANTXR1 | c.*1215C>T | 3'UTR (SNP) | VAF 21/222 reads (9%) | catalogued as rs1354938840; called by muse, mutect2
- AP002414.2 | n.742T>C | RNA (SNP) | VAF 100/233 reads (43%) | called by muse, mutect2, varscan2
- CBX5 | c.*8608C>G | 3'UTR (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- CBX8 | c.*1461C>A | 3'UTR (SNP) | VAF 33/164 reads (20%) | called by muse, mutect2, varscan2
- CUTC | c.-74T>C | 5'UTR (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- CYBC1 | c.299-74C>T | Intron (SNP) | VAF 83/175 reads (47%) | called by muse, mutect2, varscan2
- EIF4E | c.*3024G>C | 3'UTR (SNP) | VAF 9/106 reads (8%) | called by muse, mutect2
- EYA1 | c.-54-158A>T | Intron (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2
- FBN1 | c.*2069C>A | 3'UTR (SNP) | VAF 44/108 reads (41%) | called by muse, mutect2, varscan2
- HELLS | c.-59G>C | 5'UTR (SNP) | VAF 108/241 reads (45%) | catalogued as rs372598734; called by muse, mutect2, varscan2
- HPSE2 | c.*33T>G | 3'UTR (SNP) | VAF 31/92 reads (34%) | called by muse, mutect2
- HS1BP3 | c.*203G>A | 3'UTR (SNP) | VAF 155/294 reads (53%) | catalogued as rs990825239; called by muse, mutect2, varscan2
- HS3ST5 | c.*1367G>A | 3'UTR (SNP) | VAF 31/128 reads (24%) | catalogued as rs1029382795; called by muse, mutect2, varscan2
- ITPR1 | c.5197-1051C>T | Intron (SNP) | VAF 11/131 reads (8%) | called by muse, mutect2
- KAT5 | c.80-113A>C | Intron (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- KHDRBS3 | c.-302G>C | 5'UTR (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- LAMC2 | c.*922C>G | 3'UTR (SNP) | VAF 24/282 reads (9%) | called by muse, mutect2
- LPP | c.*12543T>G | 3'UTR (SNP) | VAF 51/119 reads (43%) | called by muse, mutect2, varscan2
- LRRTM4 | c.1551+170C>T | Intron (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- MAGEA5 | n.188A>G | RNA (SNP) | VAF 7/141 reads (5%) | called by muse, mutect2
- MCTP2 | c.*712T>A | 3'UTR (SNP) | VAF 18/73 reads (25%) | called by muse, mutect2, varscan2
- MPST | c.596-150A>C | Intron (SNP) | VAF 17/24 reads (71%) | called by muse, mutect2, varscan2
- MYLK | c.5239-974_5239-953del | Intron (DEL) | VAF 20/238 reads (8%) | called by mutect2, pindel
- NARF | c.108+181T>C | Intron (SNP) | VAF 34/77 reads (44%) | called by muse, mutect2, varscan2
- NOP56P1 | n.293G>T | RNA (SNP) | VAF 3/43 reads (7%) | catalogued as rs1487678066; called by muse, mutect2
- ONECUT2 | c.*9859T>C | 3'UTR (SNP) | VAF 11/51 reads (22%) | called by mutect2, varscan2
- PCDH11Y | c.*1830T>C | 3'UTR (SNP) | VAF 86/121 reads (71%) | called by muse, mutect2, varscan2
- PDZRN4 | c.844-68681A>G | Intron (SNP) | VAF 10/130 reads (8%) | catalogued as rs1299674272; called by muse, mutect2
- PGM3 | c.*3638C>T | 3'UTR (SNP) | VAF 22/186 reads (12%) | called by muse, mutect2, varscan2
- PIK3C3 | c.*5228C>G | 3'UTR (SNP) | VAF 19/175 reads (11%) | called by muse, mutect2, varscan2
- PLCB1 | c.*569T>C | 3'UTR (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- PLSCR4 | c.*52G>T | 3'UTR (SNP) | VAF 108/265 reads (41%) | called by muse, mutect2, varscan2
- PPP2R2C | c.*1810del | 3'UTR (DEL) | VAF 33/84 reads (39%) | catalogued as rs11428044; called by mutect2, varscan2
- RAD21 | c.1470+502A>T | Intron (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- RBKS | c.90-2896C>A | Intron (SNP) | VAF 98/241 reads (41%) | called by muse, mutect2, varscan2
- RBL1 | c.*1159A>G | 3'UTR (SNP) | VAF 38/100 reads (38%) | catalogued as rs1270523014; called by muse, mutect2, varscan2
- RGL3 | c.2015-88C>T | Intron (SNP) | VAF 25/59 reads (42%) | catalogued as rs898589140; called by muse, mutect2, varscan2
- RPS6KB2 | c.310-63C>G | Intron (SNP) | VAF 32/94 reads (34%) | called by muse, varscan2
- SLC35B1 | c.766+311A>C | Intron (SNP) | VAF 19/31 reads (61%) | called by mutect2, varscan2
- SLC6A11 | c.*1853G>A | 3'UTR (SNP) | VAF 45/319 reads (14%) | called by muse, mutect2, varscan2
- SLITRK1 | c.*1494C>T | 3'UTR (SNP) | VAF 20/32 reads (63%) | called by muse, mutect2, varscan2
- SMYD5 | c.*909G>A | 3'UTR (SNP) | VAF 28/178 reads (16%) | catalogued as rs193220657; called by muse, mutect2, varscan2
- TAF4 | c.*64T>A | 3'UTR (SNP) | VAF 21/308 reads (7%) | called by muse, mutect2
- THRB | c.*2433G>A | 3'UTR (SNP) | VAF 35/124 reads (28%) | called by muse, mutect2, varscan2
- TLN2 | c.*3969C>A | 3'UTR (SNP) | VAF 16/65 reads (25%) | called by muse, mutect2, varscan2
- TMEM106B | c.*3194A>G | 3'UTR (SNP) | VAF 23/53 reads (43%) | catalogued as rs1371945015; called by muse, mutect2, varscan2
- TOGARAM2 | c.-77C>A | 5'UTR (SNP) | VAF 151/529 reads (29%) | catalogued as rs1188887695; called by muse, mutect2, varscan2
- TRIM45 | c.*169G>A | 3'UTR (SNP) | VAF 11/14 reads (79%) | called by muse, mutect2, varscan2
- TSC1 | c.*1243C>T | 3'UTR (SNP) | VAF 23/337 reads (7%) | catalogued as rs896592064; called by muse, mutect2
- UBE2W | c.*6193G>C | 3'UTR (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- UBR4 | c.7213+147A>G | Intron (SNP) | VAF 41/363 reads (11%) | called by muse, mutect2, varscan2
- USP2-AS1 | n.236G>T | RNA (SNP) | VAF 26/44 reads (59%) | called by muse, mutect2, varscan2
- USP46 | c.-93G>A | 5'UTR (SNP) | VAF 15/188 reads (8%) | catalogued as rs938594771, COSV101484325; called by muse, mutect2
- WDR3 | c.*115C>G | 3'UTR (SNP) | VAF 30/87 reads (34%) | called by muse, mutect2, varscan2
- WHRN | c.-511G>C | 5'UTR (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2, varscan2
- ZNF391 | c.*397C>A | 3'UTR (SNP) | VAF 85/178 reads (48%) | catalogued as rs1391490687; called by muse, mutect2, varscan2
- ZRANB1 | c.-6T>G | 5'UTR (SNP) | VAF 27/250 reads (11%) | called by muse, mutect2, varscan2
